Somatic mutation profile of tumor specimen HTMCP-03-06-02338-01A (aliquot HTMCP-03-06-02338-01A-01D-9392) from CGCI case HTMCP-03-06-02338, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G1.
Specimen HTMCP-03-06-02338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f294009f-da1c-48d8-8e92-a920d95d58e7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02338-10A (Blood Derived Normal), aliquot HTMCP-03-06-02338-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55789b17-0b7b-4f40-8b47-ba607ecdefee

The open-access MAF lists 43 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, RNA 2, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3779+1G>A p.X1260_splice | Splice Site (SNP) | VAF 33/52 reads (63%) | catalogued as rs587783483, COSV52116972, COSV52125768, COSV52132996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRD8 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs934252386; called by muse, mutect2, varscan2
- C1QTNF6 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs757431560, COSV55397466; called by mutect2, varscan2
- CD163L1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs371920759; called by muse, mutect2, varscan2
- EP400 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs759118815; called by muse, mutect2, varscan2
- ESRP2 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52173814; called by mutect2, varscan2
- FAT4 | c.9005C>T p.T3002M | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1435573726, COSV100627638; called by muse, mutect2, varscan2
- FOCAD | c.3663G>C p.E1221D | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV58106028; called by muse, mutect2, varscan2
- GLIPR1L2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV57554722; called by muse, mutect2, varscan2
- GRM3 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64466905; called by muse, mutect2, varscan2
- KIAA0586 | c.50A>G p.H17R (on ENST00000619416 / NM_001244190.2; = p.H32R on NM_014749.5) | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1467531891, COSV53621460; called by muse, mutect2, varscan2
- LAMC1 | c.3620C>T p.T1207M | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401962127, COSV51136654; called by muse, mutect2, varscan2
- RALGAPA2 | c.2369C>T p.S790L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs780092641, COSV52487602; called by muse, mutect2, varscan2
- RIMS1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV53453330, COSV99329479; called by muse, mutect2, varscan2
- RYR2 | c.4388G>A p.R1463H | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as rs753707154, COSV100770677, COSV63662730; called by muse, mutect2, varscan2
- TNS3 | c.2710G>A p.G904R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as rs1223803012, COSV60786577; called by muse, mutect2, varscan2
- TTN | c.59408G>A p.R19803K (on ENST00000591111; = p.R12379K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/153 reads (23%) | PolyPhen probably damaging (0.987); catalogued as rs775693601, COSV60200253; called by muse, mutect2, varscan2
- ZCCHC2 | c.2345C>T p.S782L | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs199663644, COSV54041359; called by muse, mutect2, varscan2
- ZIC3 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV54977654; called by muse, mutect2, varscan2
- AKAP3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AZIN1 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC141 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DYNC2I1 | c.1739dup p.M580Ifs*5 | Frame Shift Ins (INS) | VAF 48/417 reads (12%) | called by mutect2, pindel, varscan2
- ESRP2 | c.1210G>A p.D404N (on ENST00000565858 / NM_001365264.1; = p.D394N on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM3 | c.1685G>T p.C562F | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA1 | c.1917A>T p.R639S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MPP7 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIKFYVE | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 147/234 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L1 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); called by mutect2, varscan2
- RALGAPB | c.3715G>T p.D1239Y | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBMXL1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNA1D | c.3801C>T p.D1267= (on ENST00000350061 / NM_001128840.3; = p.D1287= on NM_000720.4) | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs143841559; called by muse, mutect2, varscan2
- CNTNAP2 | c.2991T>C p.D997= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs1266451853, COSV100663928; called by muse, mutect2, varscan2
- COL1A1 | c.3600C>T p.F1200= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- DOCK3 | c.63C>T p.V21= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- EPAS1 | c.2322C>T p.G774= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- NALCN | c.3657C>T p.L1219= | Silent (SNP) | VAF 47/191 reads (25%) | catalogued as rs1566794334, COSV51929377, COSV51936438; called by muse, mutect2, varscan2
- PCDHGA2 | c.2097G>A p.A699= | Silent (SNP) | VAF 111/158 reads (70%) | catalogued as rs142588721, COSV53921180; called by muse, mutect2, varscan2
- STIP1 | c.705C>T p.A235= | Silent (SNP) | VAF 68/146 reads (47%) | called by muse, mutect2, varscan2
- ZBBX | c.129G>A p.E43= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as COSV100284999; called by muse, mutect2, varscan2
- HLA-DRB9 | n.15G>C | RNA (SNP) | VAF 39/212 reads (18%) | called by muse, mutect2, varscan2
- LINC01666 | n.494C>T | RNA (SNP) | VAF 62/524 reads (12%) | catalogued as rs1379957434; called by muse, mutect2
- TROAP | c.337+39G>A | Intron (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
